MMRF case MMRF_1511 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/742b51bb-bc36-455a-9b7c-d77be310f612

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.7 years (28,386 days); ISS stage: II; Days to last known disease status: 1,260 days (3.4 years); Days to last follow up: 1,260 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 78 days; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 777 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 777 days (2.1 years); Days to treatment end: 973 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,215 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10: M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 66.6 mg/dL; Immunoglobulin G 2.88 g/L; Immunoglobulin A 19.3 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 8.1 g/dL; Glucose 5.78 mmol/L.
- Day 110: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 3 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.94 mmol/L.
- Day 173 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 8.7 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.285 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.
- Day 265: Hemoglobin 7.13 mmol/L; Leukocytes 4.81 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Glucose 5.89 mmol/L.
- Day 293 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Glucose 4.68 mmol/L.
- Day 397 (ECOG 0): Hemoglobin 7.75 mmol/L; Leukocytes 3.11 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 524 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin A 0.857 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.89 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 48.1 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 608 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin A 1.82 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.86 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.23 mmol/L.
- Day 701 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin A 2.02 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.58 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.23 mmol/L.
- Day 727: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.46 mg/dL; Hemoglobin 8.56 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 874: M Protein 0 g/dL; Immunoglobulin A 2.38 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.77 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 6 mmol/L.
- Day 1,014: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.01 mg/dL; Immunoglobulin A 0.927 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.95 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 48.1 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 1,098: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.49 mg/dL; Immunoglobulin A 1.25 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.4 mmol/L.
- Day 1,196: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.9 mg/dL; Immunoglobulin A 1.95 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Glucose 5.39 mmol/L.
- Day 1,260: M Protein 0.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.6 mg/dL; Immunoglobulin A 1.86 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.57 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -10: Weight: 73 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1511_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1511_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
